Somatic mutation profile of tumor specimen ALCH-B3HY-TTP1-A (aliquot ALCH-B3HY-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3HY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.6 years (25,414 days).
Specimen ALCH-B3HY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb42132d-c923-4565-9991-958614ba14ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3HY-NB1-A (Blood Derived Normal), aliquot ALCH-B3HY-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dc42b17-7dc4-45e7-8c0f-12bdef6df0d6

The open-access MAF lists 284 somatic variants for this specimen: 186 protein-altering or splice-affecting, 64 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 64, Nonsense Mutation 14, Intron 12, RNA 7, 3'UTR 5, 5'Flank 4, 5'UTR 4, Frame Shift Del 3, Splice Site 2, Splice Region 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 108/329 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ABCD2 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 96/445 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs760760553; called by muse, mutect2, varscan2
- ACTR3B | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs1475104354; called by muse, mutect2
- BLOC1S4 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1416531499; called by muse, mutect2, varscan2
- BRINP3 | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as COSV66523140; called by muse, mutect2, varscan2
- C12orf40 | c.1933G>T p.G645W | Missense Mutation (SNP) | VAF 112/524 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs200701698; called by muse, varscan2
- C16orf96 | c.2812C>T p.R938W | Missense Mutation (SNP) | VAF 36/447 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1435449366; called by muse, mutect2
- C1orf68 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 48/392 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1217046707; called by muse, mutect2, varscan2
- CASKIN2 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs370216413, COSV100050703; called by muse, mutect2
- CD6 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779203131; called by muse, mutect2, varscan2
- CDCA5 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51868563; called by muse, mutect2
- COL22A1 | c.2968-1G>T p.X990_splice | Splice Site (SNP) | VAF 157/653 reads (24%) | catalogued as COSV100275825; called by muse, mutect2, varscan2
- DCSTAMP | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 131/511 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs780611938; called by muse, mutect2, varscan2
- DMRT3 | c.277G>C p.A93P | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV51902507; called by muse, mutect2, varscan2
- DNASE1L3 | c.617G>C p.R206P | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766863381, COSV59156131; called by muse, mutect2, varscan2
- DRC1 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 88/636 reads (14%) | catalogued as COSV55500876; called by muse, mutect2, varscan2
- EPHA5 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 55/862 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as rs199614818; called by muse, mutect2
- EPX | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56596911; called by muse, mutect2, varscan2
- FGD6 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs375390194; called by muse, mutect2
- GPAM | c.1178A>G p.Y393C | Missense Mutation (SNP) | VAF 69/649 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1237486372; called by muse, mutect2, varscan2
- GPC1 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141069921, COSV50865369; called by muse, mutect2, varscan2
- GPR152 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767420029; called by muse, mutect2
- IGHV1-24 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 61/864 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs552641693; called by muse, mutect2
- IRX1 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV57362444; called by muse, mutect2, varscan2
- ITGB5 | c.1946C>G p.S649C | Missense Mutation (SNP) | VAF 34/435 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as COSV56147872, COSV56151042; called by muse, mutect2
- KCNB2 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV73052636; called by muse, mutect2
- KIF21A | c.4148T>G p.L1383R (on ENST00000361418 / NM_001378440.1; = p.L1370R on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/568 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764380324; called by muse, mutect2, varscan2
- KMT2D | c.3637C>T p.Q1213* | Nonsense Mutation (SNP) | VAF 42/450 reads (9%) | catalogued as rs551485453; called by muse, mutect2
- LAMA4 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV54570432; called by mutect2, varscan2
- LHX8 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 57/517 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV53955609; called by muse, mutect2, varscan2
- LRFN2 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs543358029, COSV57835008; called by muse, mutect2, varscan2
- LRFN5 | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 53/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53243593; called by muse, mutect2, varscan2
- MAPKAPK2 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as COSV54314477; called by muse, mutect2
- MTUS2 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV70914857; called by muse, mutect2, varscan2
- MUC5B | c.9464C>T p.S3155F | Missense Mutation (SNP) | VAF 61/430 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1355248561; called by muse, mutect2, varscan2
- MYO15B | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 39/452 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.191); catalogued as rs749460132, COSV104441662; called by muse, mutect2
- MYO1B | c.887A>G p.D296G | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); catalogued as rs1486139073; called by muse, mutect2, varscan2
- NADSYN1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1424082457, COSV59814414; called by muse, mutect2
- NECTIN3 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 51/458 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV60552498, COSV60553935; called by muse, mutect2, varscan2
- NOS1 | c.2546G>T p.R849L | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV57613241; called by muse, mutect2, varscan2
- NPHS1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 84/599 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs373782564; called by muse, mutect2, varscan2
- NTRK1 | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 56/400 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs764581997, COSV104423323, COSV62323137; called by muse, mutect2, varscan2
- OR13G1 | c.539C>A p.P180Q | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV62945100; called by muse, mutect2, varscan2
- OR4C46 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1343078663, COSV100060622, COSV60219242; called by muse, mutect2
- OR5K4 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 90/583 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61583609, COSV61583793; called by muse, mutect2, varscan2
- OR6S1 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 37/310 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100289484; called by muse, mutect2
- PCNX4 | c.2185A>G p.T729A (on ENST00000406854 / NM_001330177.2; = p.T495A on NM_022495.5) | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs775391508; called by muse, mutect2
- PIK3CG | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.143); catalogued as COSV63254593; called by muse, mutect2, varscan2
- PTPRT | c.2478C>A p.D826E | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100624865; called by muse, mutect2
- RFWD3 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 24/372 reads (6%) | catalogued as COSV63097798; called by muse, mutect2
- RUNDC3B | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 52/770 reads (7%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as rs747420597; called by muse, mutect2
- SART1 | c.1261G>T p.D421Y | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56713117; called by muse, mutect2
- SDR42E1 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 17/307 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100200669; called by muse, mutect2
- SEC14L5 | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52042269; called by muse, mutect2, varscan2
- SIGLEC1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 70/656 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376249407; called by muse, mutect2, varscan2
- SLC35F6 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60426703; called by muse, mutect2, varscan2
- UBE3A | c.2057A>G p.D686G | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CD041182; called by muse, mutect2, varscan2
- ZKSCAN3 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 35/383 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV52852893; called by muse, mutect2
- ZNF286A | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 31/222 reads (14%) | catalogued as rs751666837; called by muse, mutect2, varscan2
- ZNF418 | c.1426C>G p.H476D | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101268979; called by muse, mutect2, varscan2
- ZNF71 | c.318G>T p.R106S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs373781920; called by muse, mutect2, varscan2
- ZNF729 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.987); catalogued as rs1242616897; called by muse, mutect2, varscan2
- ADARB1 | c.2167G>T p.G723W (on ENST00000360697 / NM_001346687.2; = p.G683W on NM_001112.4) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY10 | c.4306T>A p.W1436R | Missense Mutation (SNP) | VAF 64/578 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY10 | c.420C>A p.D140E | Missense Mutation (SNP) | VAF 104/955 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- AMER3 | c.465G>T p.R155S | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ANK3 | c.11572G>C p.G3858R | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.706); called by muse, mutect2
- ANKRD30A | c.1226C>A p.A409E (on ENST00000611781; = p.A353E on NM_052997.2) | Missense Mutation (SNP) | VAF 55/482 reads (11%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.587); called by mutect2, varscan2
- ANPEP | c.2312T>C p.M771T | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2
- AOC2 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 24/880 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AP4E1 | c.3058G>T p.E1020* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.1270C>G p.Q424E | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); called by muse, mutect2
- ARRB2 | c.1198A>C p.K400Q | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.027); called by muse, mutect2
- ATR | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRIP | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2
- ATXN1L | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 17/324 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2
- BRDT | c.1846A>T p.R616* | Nonsense Mutation (SNP) | VAF 22/187 reads (12%) | called by muse, varscan2
- BRWD3 | c.4657C>G p.H1553D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); called by muse, mutect2
- C16orf87 | c.463T>A p.*155Rext*102 | Nonstop Mutation (SNP) | VAF 34/138 reads (25%) | called by muse, varscan2
- C9orf40 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 66/412 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- CACNA1E | c.6320C>A p.T2107N (on ENST00000367573 / NM_001205293.3; = p.T2064N on NM_000721.4) | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.026); called by muse, mutect2
- CAMSAP3 | c.1750G>C p.G584R | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CAND1 | c.3604A>G p.I1202V | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.309); called by muse, mutect2
- CCAR1 | c.2205G>T p.W735C | Missense Mutation (SNP) | VAF 50/542 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCDC103 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CCT7 | c.1021G>C p.V341L | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.731); called by muse, mutect2
- CD300LB | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CDH10 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 116/796 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CDH18 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 64/748 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2
- CEP170 | c.1180G>C p.A394P | Missense Mutation (SNP) | VAF 48/347 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CFAP70 | c.610-1G>A p.X204_splice | Splice Site (SNP) | VAF 20/319 reads (6%) | called by muse, mutect2
- CHD8 | c.411del p.V138Sfs*69 | Frame Shift Del (DEL) | VAF 30/192 reads (16%) | called by pindel, varscan2
- CLEC14A | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2
- CLEC14A | c.813C>G p.C271W | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLUH | c.2172A>G p.P724= (on ENST00000435359; = p.P763= on NM_015229.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- CNOT1 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 32/486 reads (7%) | called by muse, mutect2
- COBL | c.3748G>A p.G1250R | Missense Mutation (SNP) | VAF 55/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A2 | c.517C>G p.P173A | Missense Mutation (SNP) | VAF 73/608 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A6 | c.1383G>T p.E461D | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- CRABP1 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2
- CSMD2 | c.1078A>T p.R360W | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CWH43 | c.1856G>T p.G619V | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DDX60L | c.1508A>G p.H503R | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- DICER1 | c.3262G>T p.D1088Y | Missense Mutation (SNP) | VAF 59/507 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DIO2 | c.246del p.N83Ifs*24 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | called by mutect2, pindel, varscan2
- DOCK10 | c.1478A>T p.Q493L | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- ENPP2 | c.1955G>A p.C652Y (on ENST00000075322 / NM_001040092.3; = p.C704Y on NM_006209.5) | Missense Mutation (SNP) | VAF 98/449 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM3C | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM83H | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXL5 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); called by muse, mutect2
- FHOD1 | c.2105C>A p.A702D | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- FOXJ3 | c.1367G>T p.W456L | Missense Mutation (SNP) | VAF 65/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GABRA5 | c.451A>C p.K151Q | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- GDPD5 | c.1235C>G p.S412* | Nonsense Mutation (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- GIMAP1 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- GMFB | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- HEATR6 | c.2439G>A p.M813I | Missense Mutation (SNP) | VAF 67/457 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPH | c.3137G>T p.C1046F (on ENST00000343002; = p.C779F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC1 | c.9001G>C p.G3001R | Missense Mutation (SNP) | VAF 44/552 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HMCN1 | c.15077G>T p.R5026L | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IZUMO1R | c.572C>A p.P191H (on ENST00000440961; = p.P198H on NM_001199206.3) | Missense Mutation (SNP) | VAF 80/782 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2
- KLF15 | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- KLHL1 | c.1502T>A p.V501E | Missense Mutation (SNP) | VAF 57/742 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KLRF1 | c.394A>T p.M132L | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- LAMA1 | c.6454G>T p.D2152Y | Missense Mutation (SNP) | VAF 173/854 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDHD | c.1118C>A p.A373D | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MFSD3 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MRC1 | c.2655G>C p.W885C | Missense Mutation (SNP) | VAF 104/1098 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MS4A10 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2
- MS4A8 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 58/815 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- MTMR7 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- MYH6 | c.3347G>C p.R1116P | Missense Mutation (SNP) | VAF 60/902 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO5B | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 117/782 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by mutect2, varscan2
- MYO9B | c.395C>G p.T132S | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NAB2 | c.827G>C p.R276P | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by mutect2, varscan2
- NFASC | c.953C>T p.A318V (on ENST00000339876 / NM_001378329.1; = p.A329V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- NONO | c.1403G>C p.R468P | Missense Mutation (SNP) | VAF 51/540 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- NTRK3 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 66/758 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); called by muse, mutect2
- NUDCD3 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2
- OR13C9 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- OR2C3 | c.937T>A p.S313T | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.01); called by mutect2, varscan2
- PCDHGA2 | c.2158C>T p.H720Y | Missense Mutation (SNP) | VAF 121/786 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCNX1 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 38/516 reads (7%) | called by muse, mutect2
- PLCL1 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PLD2 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHM1 | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 36/514 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.264); called by muse, mutect2
- PNLIP | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PPP1R12B | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 34/1244 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2
- PRDM7 | c.488A>T p.Q163L | Missense Mutation (SNP) | VAF 82/407 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PRDM9 | c.2485del p.E829Rfs*110 | Frame Shift Del (DEL) | VAF 72/614 reads (12%) | called by mutect2, varscan2
- PRKACG | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 91/406 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRMT5 | c.1500G>A p.M500I | Missense Mutation (SNP) | VAF 89/517 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PSG3 | c.516G>C p.E172D | Missense Mutation (SNP) | VAF 78/827 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.035); called by muse, mutect2
- RNASE10 | c.216C>A p.N72K | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.086); called by muse, mutect2
- RNASE12 | c.196dup p.H66Pfs*6 | Frame Shift Ins (INS) | VAF 75/470 reads (16%) | called by mutect2, pindel, varscan2
- SEL1L | c.973+3A>G | Splice Region (SNP) | VAF 49/308 reads (16%) | called by muse, mutect2, varscan2
- SENP2 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 24/201 reads (12%) | called by muse, mutect2, varscan2
- SGPP2 | c.550A>T p.R184* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- SLC39A12 | c.1247C>A p.A416D | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAB2 | c.4843C>A p.Q1615K | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.6); called by muse, mutect2
- STARD9 | c.3528G>T p.R1176S | Missense Mutation (SNP) | VAF 52/583 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SYNE1 | c.15139A>T p.S5047C (on ENST00000367255 / NM_182961.4; = p.S4976C on NM_033071.3) | Missense Mutation (SNP) | VAF 126/589 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- TCERG1 | c.635A>T p.Q212L | Missense Mutation (SNP) | VAF 120/893 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TENM4 | c.6455A>C p.K2152T | Missense Mutation (SNP) | VAF 79/489 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TIAM1 | c.1631C>G p.S544C | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM144 | c.926G>T p.W309L | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2
- TNIP2 | c.403C>A p.R135S | Missense Mutation (SNP) | VAF 64/646 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2
- TNR | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 76/527 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TSPEAR | c.446G>T p.S149I | Missense Mutation (SNP) | VAF 42/546 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2
- TTC12 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC13 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 37/391 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2
- TTN | c.62710G>T p.V20904F (on ENST00000591111; = p.V13480F on NM_003319.4) | Missense Mutation (SNP) | VAF 58/445 reads (13%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.11057G>T p.R3686M (on ENST00000591111; = p.R3640M on NM_003319.4) | Missense Mutation (SNP) | VAF 44/398 reads (11%) | called by muse, mutect2, varscan2
- UQCRHL | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 20/607 reads (3%) | called by muse, mutect2
- USH1C | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 138/859 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH2A | c.1982A>G p.Q661R | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2
- VSIG2 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- VWC2 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XPC | c.1505C>G p.S502* | Nonsense Mutation (SNP) | VAF 21/531 reads (4%) | called by muse, mutect2
- ZBTB38 | c.2899C>A p.Q967K | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF418 | c.1561C>G p.Q521E | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF442 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 62/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF467 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 47/314 reads (15%) | called by muse, mutect2, varscan2
- ZNF524 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF577 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.2004C>G p.D668E | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2
- ARHGAP15 | c.604C>T p.L202= | Silent (SNP) | VAF 25/308 reads (8%) | catalogued as rs759348173, COSV54519144; called by muse, mutect2
- ASXL2 | c.48C>A p.A16= | Silent (SNP) | VAF 57/450 reads (13%) | called by muse, mutect2, varscan2
- AZGP1 | c.816G>T p.P272= | Silent (SNP) | VAF 48/472 reads (10%) | catalogued as rs757379266; called by muse, mutect2, varscan2
- BAHCC1 | c.72C>A p.A24= | Silent (SNP) | VAF 24/120 reads (20%) | called by muse, mutect2, varscan2
- BCAN | c.1869C>T p.T623= | Silent (SNP) | VAF 52/350 reads (15%) | catalogued as rs746606462; called by muse, mutect2, varscan2
- CACNA2D2 | c.1836C>T p.S612= | Silent (SNP) | VAF 39/255 reads (15%) | called by muse, mutect2, varscan2
- CCDC7 | c.3777G>A p.V1259= | Silent (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2
- CHST8 | c.600C>A p.A200= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV52859821; called by muse, mutect2, varscan2
- CLUH | c.1581C>T p.P527= (on ENST00000435359; = p.P565= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- COL4A2 | c.2073G>T p.L691= | Silent (SNP) | VAF 39/498 reads (8%) | called by muse, mutect2
- COL8A1 | c.1536T>C p.P512= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- DACT1 | c.2077A>C p.R693= | Silent (SNP) | VAF 40/307 reads (13%) | catalogued as rs747322707, COSV60021428; called by muse, mutect2, varscan2
- DDR2 | c.1785A>G p.L595= | Silent (SNP) | VAF 96/837 reads (11%) | called by muse, mutect2, varscan2
- DIP2C | c.3558G>T p.L1186= | Silent (SNP) | VAF 45/433 reads (10%) | called by muse, mutect2, varscan2
- DPYD | c.1776G>T p.R592= | Silent (SNP) | VAF 16/394 reads (4%) | called by muse, mutect2
- EIF2B4 | c.552C>T p.P184= (on ENST00000347454 / NM_001034116.2; = p.P183= on NM_015636.3) | Silent (SNP) | VAF 86/678 reads (13%) | called by muse, mutect2, varscan2
- EP400 | c.8790G>T p.L2930= | Silent (SNP) | VAF 48/453 reads (11%) | catalogued as COSV100201831; called by muse, mutect2, varscan2
- EPHA5 | c.1251G>T p.R417= | Silent (SNP) | VAF 52/856 reads (6%) | called by muse, mutect2
- EPX | c.1308C>T p.P436= | Silent (SNP) | VAF 68/502 reads (14%) | called by muse, mutect2, varscan2
- EYS | c.1158G>A p.K386= | Silent (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2
- FAM155A | c.1167C>A p.S389= | Silent (SNP) | VAF 166/794 reads (21%) | called by muse, varscan2
- FRG2C | c.168A>T p.T56= | Silent (SNP) | VAF 45/1410 reads (3%) | called by muse, mutect2
- FSIP2 | c.7639T>C p.L2547= | Silent (SNP) | VAF 22/204 reads (11%) | called by muse, varscan2
- H1-2 | c.66G>A p.K22= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs759536174, COSV104415406, COSV59191802; called by muse, mutect2, varscan2
- H2BC10 | c.213C>T p.F71= | Silent (SNP) | VAF 35/287 reads (12%) | catalogued as COSV59952580; called by muse, mutect2, varscan2
- HES4 | c.465C>T p.R155= | Silent (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2, varscan2
- HYDIN | c.5649C>T p.S1883= | Silent (SNP) | VAF 115/665 reads (17%) | called by muse, mutect2, varscan2
- IGKV2-30 | c.108A>G p.G36= | Silent (SNP) | VAF 46/472 reads (10%) | catalogued as rs539273566; called by muse, mutect2, varscan2
- ITGB4 | c.957C>A p.I319= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- LDHD | c.1119C>A p.A373= | Silent (SNP) | VAF 42/240 reads (18%) | called by muse, mutect2, varscan2
- MCOLN1 | c.1536C>T p.L512= | Silent (SNP) | VAF 105/756 reads (14%) | called by muse, mutect2, varscan2
- MPP2 | c.663C>T p.P221= (on ENST00000461854 / NM_001278372.2; = p.P197= on NM_005374.5) | Silent (SNP) | VAF 59/435 reads (14%) | called by muse, mutect2, varscan2
- MROH9 | c.1695C>A p.I565= | Silent (SNP) | VAF 22/195 reads (11%) | called by muse, mutect2, varscan2
- MXRA5 | c.4818C>T p.T1606= | Silent (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
- MYH2 | c.3843G>A p.A1281= | Silent (SNP) | VAF 127/843 reads (15%) | catalogued as rs1062469; called by muse, mutect2, varscan2
- NCK2 | c.1011C>T p.L337= | Silent (SNP) | VAF 34/436 reads (8%) | called by muse, mutect2
- NEK3 | c.1227A>G p.K409= | Silent (SNP) | VAF 39/375 reads (10%) | called by muse, mutect2, varscan2
- NEU3 | c.964C>T p.L322= | Silent (SNP) | VAF 31/380 reads (8%) | called by muse, mutect2
- NFASC | c.3057C>A p.L1019= | Silent (SNP) | VAF 53/494 reads (11%) | called by muse, mutect2, varscan2
- NUDT17 | c.747G>A p.E249= | Silent (SNP) | VAF 46/360 reads (13%) | called by muse, mutect2, varscan2
- OR10K1 | c.729C>A p.S243= | Silent (SNP) | VAF 83/732 reads (11%) | called by muse, mutect2, varscan2
- OR10T2 | c.441T>C p.S147= | Silent (SNP) | VAF 61/582 reads (10%) | catalogued as COSV57781531; called by muse, mutect2, varscan2
- OR4K15 | c.369C>G p.A123= (on ENST00000305051; = p.A99= on NM_001005486.1) | Silent (SNP) | VAF 19/298 reads (6%) | catalogued as COSV100520957, COSV59300713; called by muse, mutect2
- PDPR | c.1878G>A p.L626= | Silent (SNP) | VAF 45/740 reads (6%) | called by muse, mutect2
- PRKAR1B | c.957A>T p.G319= | Silent (SNP) | VAF 61/325 reads (19%) | called by muse, mutect2, varscan2
- PRKCB | c.963G>A p.T321= | Silent (SNP) | VAF 28/264 reads (11%) | catalogued as rs766756709, COSV57802987; called by muse, mutect2
- RASAL2 | c.2035T>C p.L679= | Silent (SNP) | VAF 34/334 reads (10%) | called by muse, mutect2
- RXFP2 | c.1809C>A p.L603= | Silent (SNP) | VAF 42/460 reads (9%) | catalogued as COSV53633079; called by muse, mutect2
- SART1 | c.1260A>T p.A420= | Silent (SNP) | VAF 29/367 reads (8%) | called by muse, mutect2
- SHB | c.1443C>A p.V481= | Silent (SNP) | VAF 74/492 reads (15%) | called by muse, mutect2, varscan2
- SLC22A11 | c.996G>T p.S332= | Silent (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- SLC22A12 | c.1464G>T p.L488= | Silent (SNP) | VAF 54/717 reads (8%) | catalogued as rs1167124427; called by muse, mutect2
- SMTNL2 | c.1095G>A p.T365= (on ENST00000389313 / NM_001114974.2; = p.T221= on NM_198501.3) | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs547597629; called by muse, mutect2, varscan2
- SPP2 | c.396T>A p.A132= | Silent (SNP) | VAF 43/311 reads (14%) | called by muse, mutect2, varscan2
- TAF4 | c.2808G>A p.Q936= | Silent (SNP) | VAF 28/231 reads (12%) | called by muse, mutect2, varscan2
- TBX18 | c.141G>A p.A47= | Silent (SNP) | VAF 97/486 reads (20%) | called by muse, mutect2, varscan2
- TM9SF4 | c.1113G>A p.S371= | Silent (SNP) | VAF 65/452 reads (14%) | catalogued as rs760563426; called by muse, varscan2
- TMEM30B | c.480G>A p.A160= | Silent (SNP) | VAF 65/403 reads (16%) | called by muse, mutect2, varscan2
- TRPM1 | c.1162C>A p.R388= | Silent (SNP) | VAF 86/988 reads (9%) | catalogued as COSV56637756; called by muse, mutect2
- TUBB8 | c.507C>T p.I169= | Silent (SNP) | VAF 61/1144 reads (5%) | catalogued as rs781829518; called by muse, mutect2
- TUBGCP5 | c.1443G>A p.V481= | Silent (SNP) | VAF 33/273 reads (12%) | called by muse, mutect2, varscan2
- UBXN2B | c.117G>A p.V39= | Silent (SNP) | VAF 45/514 reads (9%) | catalogued as COSV68308527; called by muse, mutect2
- USP17L1 | c.1017C>G p.V339= | Silent (SNP) | VAF 37/1348 reads (3%) | catalogued as rs1350083100; called by muse, mutect2
- ZNF615 | c.813G>A p.K271= | Silent (SNP) | VAF 41/320 reads (13%) | catalogued as COSV65031932; called by muse, mutect2, varscan2
- AC107023.1 | n.25+3090G>A | Intron (SNP) | VAF 49/303 reads (16%) | called by muse, mutect2, varscan2
- ADAM10 | c.207-16042G>A | Intron (SNP) | VAF 17/204 reads (8%) | called by muse, mutect2
- ADAM20P1 | n.859G>A | RNA (SNP) | VAF 50/315 reads (16%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827094 G>A | 3'Flank (SNP) | VAF 33/181 reads (18%) | catalogued as rs1158041494; called by muse, mutect2, varscan2
- AUP1 | c.-58C>T | 5'UTR (SNP) | VAF 30/186 reads (16%) | called by muse, mutect2, varscan2
- CBX2 | c.288+126A>T | Intron (SNP) | VAF 65/527 reads (12%) | called by muse, mutect2, varscan2
- CLN5 | chr13:76991915 T>C | 5'Flank (SNP) | VAF 50/560 reads (9%) | called by muse, mutect2
- DIAPH3 | c.2737+26C>T | Intron (SNP) | VAF 34/234 reads (15%) | catalogued as rs1274006724, COSV57365120; called by muse, mutect2, varscan2
- EFHC1 | c.*7G>T | 3'UTR (SNP) | VAF 40/206 reads (19%) | called by muse, mutect2, varscan2
- EXT2 | c.*40A>T | 3'UTR (SNP) | VAF 18/299 reads (6%) | called by muse, mutect2
- FAM161A | c.*136G>C | 3'UTR (SNP) | VAF 72/506 reads (14%) | called by muse, mutect2, varscan2
- FAM205BP | n.1785C>T | RNA (SNP) | VAF 189/1787 reads (11%) | called by muse, mutect2, varscan2
- FXR2 | c.81+391C>G | Intron (SNP) | VAF 38/316 reads (12%) | catalogued as rs988547507; called by muse, mutect2, varscan2
- IGFN1 | c.1242-2754A>T | Intron (SNP) | VAF 64/699 reads (9%) | called by muse, mutect2
- IGKV1D-27 | n.240C>T | RNA (SNP) | VAF 46/832 reads (6%) | catalogued as rs749114865; called by muse, mutect2
- IGLL5 | chr22:22901053 G>T | 3'Flank (SNP) | VAF 125/1303 reads (10%) | catalogued as rs1212623575; called by muse, mutect2
- KCNK16 | c.802+12G>T | Intron (SNP) | VAF 72/371 reads (19%) | called by muse, mutect2, varscan2
- KIAA1958 | chr9:112486406 G>T | 5'Flank (SNP) | VAF 25/800 reads (3%) | called by muse, mutect2
- MSL3P1 | n.763G>C | RNA (SNP) | VAF 26/214 reads (12%) | called by muse, mutect2, varscan2
- NKAIN3 | c.472-55226T>C | Intron (SNP) | VAF 108/498 reads (22%) | called by muse, mutect2, varscan2
- PAGE5 | c.-78G>T | 5'UTR (SNP) | VAF 26/120 reads (22%) | called by muse, varscan2
- PCF11 | c.2092+203G>T | Intron (SNP) | VAF 62/591 reads (10%) | called by muse, mutect2, varscan2
- PHGDH | c.356+1427C>T | Intron (SNP) | VAF 41/906 reads (5%) | called by muse, mutect2
- PHIP | c.-16G>A | 5'UTR (SNP) | VAF 39/324 reads (12%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*42T>C | 3'UTR (SNP) | VAF 33/663 reads (5%) | called by muse, mutect2
- PTK2 | c.-32-30087G>A | Intron (SNP) | VAF 24/404 reads (6%) | called by muse, mutect2
- RIC8A | c.-38G>A | 5'UTR (SNP) | VAF 29/209 reads (14%) | catalogued as COSV100254653; called by muse, mutect2, varscan2
- SKA3 | c.*52C>A | 3'UTR (SNP) | VAF 32/364 reads (9%) | called by muse, mutect2
- SNORD113-9 | n.23G>T | RNA (SNP) | VAF 24/221 reads (11%) | catalogued as rs758210203; called by muse, mutect2, varscan2
- SPATA31C2 | n.3305A>T | RNA (SNP) | VAF 130/1126 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.4745C>T | RNA (SNP) | VAF 11/92 reads (12%) | catalogued as rs747516946; called by muse, mutect2, varscan2
- SUCO | chr1:172532569 C>A | 5'Flank (SNP) | VAF 99/902 reads (11%) | catalogued as rs77025284; called by muse, varscan2
- TTYH1 | chr19:54415233 G>A | 5'Flank (SNP) | VAF 61/481 reads (13%) | called by muse, mutect2, varscan2
- UCHL3 | c.475-4915G>T | Intron (SNP) | VAF 35/313 reads (11%) | catalogued as rs1163316069; called by muse, mutect2, varscan2
